Gene-level copy-number profile of tumor specimen RC-B56Q-TTP1-A from RC case RC-B56Q, project RC-PTCL: Refractory Cancers (RC) - Peripheral T-Cell Lymphoma (PTCL). Sex at birth: female; Vital status: Dead; Primary diagnosis: Extranodal NK/T-cell lymphoma, nasal type; Tissue or organ of origin: Lymph node, NOS; Age at diagnosis: 69.4 years (25,332 days).
Specimen RC-B56Q-TTP1-A: Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 56100a4a-3aaf-454e-9ccb-a1c1f1bed45c.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator RC-B56Q-NB1-B; Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,222 have no estimate.
https://portal.gdc.cancer.gov/files/0ce0406e-8251-448a-88ec-2fb3869e520c

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 4; copy number 1: 3,962; copy number 2: 51,732; copy number 3: 2,466; copy number 4: 7; copy number 5: 30; copy number 6: 64; copy number 7: 6; copy number 8: 7; copy number 10: 30; copy number 11: 23; copy number 13: 70.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 230 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:12,674,421–14,520,344, 36 genes, copy number 5–7 (within-gene range 3–7): TEAD1, AC013549.3, AC013549.4, AC013549.2, AC013549.1, LINC00958, RASSF10-DT, RASSF10, AC013762.1, AC022878.1, ARNTL, RN7SKP151, BTBD10, AC021269.1, AC021269.2, PTH, HMGN2P36, FAR1, FAR1-IT1, RPL39P26, Y_RNA, CENPUP1, AC013828.1, LINC02548, AC027779.1, LINC02545, RNA5SP331, LINC02683, SPON1, RNA5SP332, SPON1-AS1, RRAS2, AC018523.1, COPB1, RNU7-49P, AC018523.2.
- chr20:35,953,617–37,095,997, 30 genes, copy number 8–11 (within-gene range 4–11): SCAND1, CNBD2, NORAD, AL035420.1, AL035420.3, HMGB3P2, AL035420.2, EPB41L1, AL121895.1, AL121895.2, AAR2, DLGAP4, DLGAP4-AS1, MYL9, Metazoa_SRP, TGIF2, TGIF2-RAB5IF, RAB5IF, SLA2, HNRNPA3P2, NDRG3, Y_RNA, DSN1, SOGA1, RN7SL156P, TLDC2, SAMHD1, RBL1, RPS3AP3, RPS27AP3.
- chr20:37,444,733–45,348,424, 164 genes, copy number 6–13 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 2,190. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
